Gene-level copy-number profile of tumor specimen TCGA-30-1867-01A from TCGA case TCGA-30-1867, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: GX; Age at diagnosis: 47.0 years (17,159 days).
Specimen TCGA-30-1867-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.54dedb5e-643b-49fc-8225-4bd46bd46c82.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-30-1867-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/055e4005-e565-4ff8-b47e-a68aa840a547

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 836; copy number 2: 10,337; copy number 3: 27,250; copy number 4: 13,878; copy number 5: 5,775; copy number 6: 188; copy number 7: 363; copy number 8: 530; copy number 9: 206; copy number 10: 240; copy number 12: 19; copy number 13: 1; copy number 15: 2; copy number 16: 20; copy number 17: 28; copy number 18: 55; copy number 23: 63; copy number 28: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-30-1867-01): tumor purity 0.51, ploidy 3.39, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,237,358–181,265,145, 2 genes: AC019235.1, LINC02500.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,320 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:100,722,221–102,058,190, 26 genes, copy number 7: AC092168.1, AC092168.3, NPAS2, AC092168.2, NPAS2-AS1, AC016738.1, RPL31, TBC1D8, BBIP1P1, TBC1D8-AS1, CNOT11, RNF149, SNORD89, MIR5696, CREG2, AC092570.1, RFX8, LINC01870, RPS6P3, PRCPP1, AC093894.1, AC093894.2, MAP4K4, LINC01127, IL1R2, AC007271.1.
- chr7:14,985,378–24,132,837, 131 genes, copy number 8–28 (broad region; genes not listed).
- chr10:73,098,044–81,137,335, 200 genes, copy number 7–23 (within-gene range 6–23) (broad region; genes not listed).
- chr17:48,377,262–48,633,572, 18 genes, copy number 10 (within-gene range 3–10): AC036222.2, U3, AC036222.1, Y_RNA, HOXB1, HOXB2, HOXB-AS1, HOXB3, HOXB-AS3, HOXB-AS2, HOXB4, AC103702.1, MIR10A, HOXB5, HOXB6, HOXB7, HOXB8, HOXB9.
- chr17:76,563,710–76,807,102, 20 genes, copy number 7 (within-gene range 3–7): AC015802.6, ST6GALNAC2, AC015802.1, AC015802.2, AC015802.7, ST6GALNAC1, RNU6-227P, AC005837.1, MXRA7, RNY4P36, AC005837.4, JMJD6, AC005837.3, METTL23, AC005837.2, SRSF2, MFSD11, MIR636, RNU6-97P, LINC02080.
- chr19:17,323,223–20,571,095, 178 genes, copy number 8 (broad region; genes not listed).
- chr19:27,793,431–27,984,984, 1 gene, copy number 8 (within-gene range 4–8): AC006504.5.
- chr19:27,849,635–34,872,479, 163 genes, copy number 8 (broad region; genes not listed).
- chr20:87,250–8,043,512, 211 genes, copy number 7–17 (broad region; genes not listed).
- chr20:8,097,824–8,099,774, 1 gene, copy number 7: PHKBP1.
- chr20:52,972,358–53,495,330, 1 gene, copy number 16 (within-gene range 5–16): TSHZ2.
- chr20:53,255,979–54,651,169, 20 genes, copy number 13–16: AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1, DOK5.
- chr20:56,267,872–64,313,132, 255 genes, copy number 7–8 (broad region; genes not listed).
- chr21:14,216,130–19,900,043, 84 genes, copy number 7 (broad region; genes not listed).
- chr21:32,628,759–33,071,104, 11 genes, copy number 7 (within-gene range 4–7): SYNJ1, PAXBP1-AS1, PAXBP1, C21orf62-AS1, AP000280.2, C21orf62, AP000281.1, SNORA70, AP000281.2, AP000282.1, LINC01690.

Autosomal genes at a single copy (total copy number 1): 836. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
